Somatic mutation profile of tumor specimen TARGET-50-PAJLWT-01A (aliquot TARGET-50-PAJLWT-01A-01D) from TARGET case TARGET-50-PAJLWT, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.5 years (1,262 days).
Specimen TARGET-50-PAJLWT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d46cee2-7a7c-4090-b2f5-d8e575613b67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJLWT-10A (Blood Derived Normal), aliquot TARGET-50-PAJLWT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fe9ca41-9614-4608-bf27-916a895f5735

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 2, Missense Mutation 2, Intron 1, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2980del p.E994Sfs*27 | Frame Shift Del (DEL) | VAF 70/95 reads (74%) | catalogued as COSV60718396; called by mutect2, pindel, varscan2
- TNRC18 | c.3318del p.D1106Efs*53 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as COSV101269726, COSV68169392, COSV68171659; called by mutect2, pindel, varscan2
- VPS13B | c.11797C>T p.P3933S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs967218114, COSV62153739; called by muse, mutect2, varscan2
- AGK | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); called by muse, mutect2
- MN1 | c.2691_2696dup p.S898_S899dup | In Frame Ins (INS) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- OR4C3 | c.108G>A p.T36= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as rs78490540; called by muse, mutect2, varscan2
- ATP6V0B | c.400+13G>A | Intron (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
